Surgical pathology report (de-identified scan), TCGA case TCGA-KC-A4BL, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Cornell Medical College, specimen TCGA-KC-A4BL-01A (Primary Tumor).

[page 1 of 2]
A: Right neurovascular margin (frozen section)

B: Prostate and seminal vesicles

C: Bilateral lymph nodes

CLINICAL INFORMATION:

Prostate cancer.

Specimen submitted: A. Right neurovascular margin (frozen section); B. Prostate and seminal vesicles; C. Bilateral lymph nodes

FROZEN SECTION DIAGNOSIS:

A. Frozen Section Diagnosis: Fibroadipose tissue with nerve. Negative for carcinoma or prostatic glands. (Reported to

GROSS DESCRIPTION:

A. Received fresh, the specimen is labeled "right neurovascular margin (f.s.)," and consists of a 0.3 x 0.2 x 0.1 cm piece of red soft tissue frozen in its entirety for frozen section diagnosis. Summary of sections: AFSC-frozen section control.

B. Received fresh, the specimen is labeled "prostate and seminal vesicles", and consists of a 21 gram radical prostatectomy specimen including a 3.0 x 2.5 x 2.5 cm prostate, a 2.5 x 1.2 x 0.5 cm left seminal vesicle, a 2.0 x 0.5 x 0.4 cm left vas deferens, a 2.0 x 1.0 x 0.5 cm right seminal vesicle and a 2.0 x 0.5 x 0.4 cm right vas deferens. The right side of the specimen is inked green and the left side is inked black. The seminal vesicle base, bladder neck and apical margins are shaved and submitted. The prostate is serially sectioned from the apex to base with sections designated from A to F respectively. On sectioning, multiple nodular and cystic areas are seen. The prostate is submitted in its entirety. Summary of sections: B1-right seminal vesicle and vas deferens; B2-left seminal vesicle and vas deferens; B3-right bladder neck margin; B4-left bladder neck margin; B5-right apical margin; B6-left apical margin; B7-level A margin; B8-level B margin; B9- ; B10- B11- B12- ; B13- B14- B15- B16- B17- ; B18- B19- B20- ; B21- ; B22- ; B23- ; B24- .

Note: (R=Right; L=Left; A=Anterior; P=posterior).

C. Received fresh, the specimen is labeled "bilateral lymph nodes," and consists of a 3.0 x 1.5 x 0.8 cm piece of fatty tissue and lymph nodes. 100% submitted. Summary of sections: C1-C2.

DIAGNOSIS:

A. Right neurovascular margin (biopsy):

Fibromuscular tissue and nerve.

No prostatic glands or carcinoma seen.

B. Prostate and seminal vesicles (radical prostatectomy):

Adenocarcinoma of the prostate, Gleason score 7 (3+4), with focal areas of Gleason grade 5.

- The tumor is present in both lobes and

ICD-O-3
CCCF: Adenocarcinoma, acinar
p1th: Adenocarcinoma, NOS 8140/3
Site: Prostate, NOS C61.9
8550/3
9/26/12

[page 2 of 2]
located primarily in the peripheral zone.

- The tumor involves approximately 20-30% of the submitted tissue.

- Extraprostatic extension is not identified.

- The seminal vesicles, bladder neck and apical margins, as well as all inked peripheral surgical margins are free of tumor.

- Prominent perineural invasion is identified.

- No angiolymphatic invasion is identified.

C. Bilateral lymph nodes (excision):

Four lymph nodes, negative for metastatic carcinoma (0/4).

Resulting Agency

Result Narrative

Ordered by an unspecified provider.

Order Information Lab Collection Information, Order Information, Order Providers

HPV-A Discrepancy		✓

Source: NCI Genomic Data Commons file 9cf98e99-5ac4-4572-9fd4-fe58a4c69d99 (TCGA-KC-A4BL.EEF5303A-D63A-4D2F-A8B6-A78437A583FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).